Somatic mutation profile of tumor specimen ALCH-B1S0-TTP1-A (aliquot ALCH-B1S0-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1S0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,748 days).
Specimen ALCH-B1S0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb503a8f-780c-42b8-b32e-5f7f698769f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1S0-NB1-A (Blood Derived Normal), aliquot ALCH-B1S0-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6cac40e-a0e7-4bc6-be75-d7a4e74d710d

The open-access MAF lists 3,383 somatic variants for this specimen: 2,287 protein-altering or splice-affecting, 682 silent, 414 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,909, Silent 682, Nonsense Mutation 195, Intron 178, RNA 73, Splice Site 67, 5'UTR 64, Frame Shift Del 63, 3'UTR 58, Splice Region 31, 5'Flank 24, Frame Shift Ins 19.

Variants (750 of 3,383; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.6928C>T p.Q2310* | Nonsense Mutation (SNP) | VAF 41/334 reads (12%) | catalogued as rs745997770; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BTK | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs128621202, CM940197, COSV58117884, COSV58122224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPOX | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917872, CM024099; ClinVar: pathogenic; called by muse, mutect2
- F11 | c.1325del p.L442Cfs*8 | Frame Shift Del (DEL) | VAF 41/248 reads (17%) | catalogued as rs757530565; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 52/335 reads (16%) | catalogued as rs1567847905, CM1110584, COSV62191872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTC | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs72554331, CM930521; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 147/541 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- A4GNT | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs776276585; called by muse, mutect2, varscan2
- ABCA3 | c.1612-2A>T p.X538_splice | Splice Site (SNP) | VAF 24/127 reads (19%) | catalogued as CS057374, COSV57050999; called by muse, mutect2, varscan2
- ABCA8 | c.2096C>A p.S699* | Nonsense Mutation (SNP) | VAF 24/170 reads (14%) | catalogued as COSV52194545; called by muse, mutect2, varscan2
- ABCA9 | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs772870876, COSV100383418, COSV60630364; called by muse, mutect2, varscan2
- ABCB4 | c.1875C>G p.F625L | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV99711364; called by muse, mutect2, varscan2
- ABCC8 | c.143T>A p.F48Y | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56851536; called by muse, mutect2, varscan2
- ABHD2 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61773798; called by muse, mutect2, varscan2
- ACCSL | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV66581802; called by muse, mutect2, varscan2
- ACOX1 | c.109+3G>A | Splice Region (SNP) | VAF 18/57 reads (32%) | catalogued as rs1228781448; called by muse, mutect2, varscan2
- ACTL10 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55775627, COSV99864534; called by muse, mutect2, varscan2
- ACTN2 | c.1040C>G p.T347R | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63976158; called by muse, mutect2, varscan2
- ACTN2 | c.2035A>T p.K679* | Nonsense Mutation (SNP) | VAF 46/377 reads (12%) | catalogued as COSV63973763; called by muse, mutect2, varscan2
- ACTRT1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV100947496; called by muse, mutect2, varscan2
- ACTRT2 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV101007596; called by muse, mutect2, varscan2
- ADAM15 | c.1269C>G p.F423L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55129615; called by muse, mutect2, varscan2
- ADAM23 | c.874C>A p.R292S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV52210928; called by muse, mutect2
- ADAM9 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1295134926; called by muse, mutect2, varscan2
- ADAMTS13 | c.3227G>T p.W1076L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV63022299; called by muse, mutect2, varscan2
- ADAMTS15 | c.1981G>C p.G661R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.949); catalogued as COSV100143891; called by muse, mutect2, varscan2
- ADAMTS17 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); catalogued as rs1311123714; called by muse, mutect2, varscan2
- ADAMTS18 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV51399595; called by muse, mutect2, varscan2
- ADAMTS2 | c.1163C>A p.P388Q | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51075491; called by muse, mutect2, varscan2
- ADAMTS5 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.361); catalogued as rs1277339016, COSV53179394; called by muse, mutect2
- ADAMTSL1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs368567865; called by muse, mutect2, varscan2
- ADCYAP1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as rs750759089, COSV52486250; called by muse, mutect2, varscan2
- ADGRD2 | c.2810G>A p.S937N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1310045831; called by muse, mutect2, varscan2
- ADGRL3 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV72268456, COSV72269289; called by muse, mutect2, varscan2
- ADGRV1 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866072363; called by muse, varscan2
- ADGRV1 | c.15830G>T p.R5277L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV67983919; called by muse, mutect2, varscan2
- ADORA1 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.075); catalogued as COSV55143619; called by muse, mutect2, varscan2
- ADRA1B | c.1274C>A p.S425* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV60705018; called by muse, varscan2
- AGBL1 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV101223272; called by muse, mutect2, varscan2
- AHNAK | c.11317G>A p.D3773N | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV99946461; called by muse, mutect2, varscan2
- AHNAK2 | c.2206G>T p.D736Y | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV60921937; called by muse, mutect2, varscan2
- AL662899.2 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as COSV63263740; called by muse, mutect2
- ALB | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99890439; called by mutect2, varscan2
- ALKBH6 | c.400G>T p.V134L (on ENST00000252984 / NM_001297701.2; = p.V162L on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53324374; called by muse, mutect2, varscan2
- ALPK2 | c.4847G>A p.G1616E | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV64492252; called by muse, mutect2, varscan2
- AMPH | c.1158+1del p.X386_splice | Splice Site (DEL) | VAF 55/261 reads (21%) | catalogued as COSV57762532; called by mutect2, pindel, varscan2
- ANK1 | c.4667A>G p.E1556G | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1255242079, COSV99224745; called by muse, mutect2
- ANKUB1 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1228176647; called by muse, mutect2, varscan2
- ANLN | c.2606A>T p.Q869L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV56077418; called by muse, mutect2
- APBA3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs769981121, COSV100349729; called by muse, mutect2, varscan2
- APBB1IP | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs779560771, COSV63076096, COSV63076563; called by muse, mutect2, varscan2
- APC | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57333293; called by muse, mutect2, varscan2
- APOB | c.9283C>T p.Q3095* | Nonsense Mutation (SNP) | VAF 34/255 reads (13%) | catalogued as COSV51935862; called by muse, mutect2, varscan2
- APOB | c.3496G>T p.A1166S | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as rs938330169, COSV99268237; called by muse, mutect2, varscan2
- APOBR | c.3251G>T p.R1084L (on ENST00000431282; = p.R1093L on NM_018690.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs773504779, COSV99076702; called by muse, mutect2, varscan2
- APOD | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279679431, COSV58402814; called by muse, mutect2, varscan2
- AQR | c.2065G>T p.D689Y | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50030780; called by muse, mutect2, varscan2
- ARAF | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV51692898; called by muse, mutect2, varscan2
- ARHGAP15 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 31/163 reads (19%) | catalogued as COSV54480793, COSV54514102; called by muse, mutect2, varscan2
- ARHGAP6 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1385126405; called by muse, mutect2, varscan2
- ASIC1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1191945853; called by muse, mutect2
- ASNS | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs1461068861, COSV99446120; called by muse, mutect2, varscan2
- ASPDH | c.785C>A p.T262K (on ENST00000389208 / NM_001114598.2; = p.T157K on NM_001024656.3) | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.236); catalogued as rs769179022, COSV65350402; called by muse, mutect2, varscan2
- ASTN1 | c.3437C>A p.P1146H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100708001, COSV100708026; called by muse, mutect2, varscan2
- ASTN1 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56068766; called by muse, mutect2, varscan2
- ASXL2 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55465440; called by muse, mutect2, varscan2
- ATAD2 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs766994411; called by muse, mutect2, varscan2
- ATF7IP | c.3136C>G p.Q1046E | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs753994466, COSV53774800; called by muse, mutect2, varscan2
- ATG12 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57242564; called by muse, mutect2
- ATP13A4 | c.2980C>G p.Q994E | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV61329229; called by muse, mutect2, varscan2
- ATP2A2 | c.1472G>C p.R491T | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58043474; called by muse, mutect2, varscan2
- ATP6AP2 | c.530A>T p.N177I | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV65798275; called by muse, mutect2, varscan2
- ATP8A2 | c.1769A>G p.Y590C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs745664350; called by muse, mutect2, varscan2
- AXIN2 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs773119996; called by mutect2, varscan2
- B4GALT3 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV60526803; called by muse, mutect2, varscan2
- BACE1 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); catalogued as rs1001067796; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1492C>G p.R498G | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50055158; called by muse, mutect2
- BANK1 | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.618); catalogued as rs774869173; called by muse, mutect2, varscan2
- BCL10 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65354078; called by muse, mutect2, varscan2
- BCO2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100730452; called by muse, mutect2, varscan2
- BFAR | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV99902235; called by muse, varscan2
- BHLHE22 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.482); catalogued as COSV58861732; called by muse, varscan2
- BMPER | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 67/467 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1483511272, COSV51819417; called by muse, mutect2, varscan2
- BOC | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 46/136 reads (34%) | catalogued as COSV56346583; called by muse, mutect2, varscan2
- BRAT1 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs756690295; called by muse, mutect2, varscan2
- BRIP1 | c.2329del p.R777Vfs*4 | Frame Shift Del (DEL) | VAF 71/437 reads (16%) | catalogued as COSV51998004; called by mutect2, pindel, varscan2
- BTBD6 | c.929G>C p.S310T | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs61742282; called by muse, mutect2, varscan2
- C20orf144 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1423760911, COSV99865189; called by muse, mutect2, varscan2
- C2CD4C | c.378del p.D127Tfs*79 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | catalogued as COSV100173716; called by mutect2, pindel, varscan2
- C6 | c.1958G>C p.G653A | Missense Mutation (SNP) | VAF 81/645 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV54706552; called by muse, mutect2, varscan2
- CACNA1C | c.1841T>C p.L614P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057518994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1F | c.842C>A p.S281* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV59906972; called by muse, varscan2
- CACNG5 | c.717G>C p.R239S | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50056461; called by muse, mutect2, varscan2
- CADPS2 | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 166/596 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57375877; called by muse, mutect2, varscan2
- CALCR | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated, low confidence (0.94); PolyPhen probably damaging (0.986); catalogued as rs1251411115; called by muse, varscan2
- CALML3 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1485309408; called by muse, mutect2, varscan2
- CAMK1G | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as rs140469539; called by muse, mutect2, varscan2
- CARNS1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs548198385; called by muse, mutect2, varscan2
- CATSPERE | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs760395251; called by muse, mutect2, varscan2
- CBR1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs1476785218; called by muse, mutect2, varscan2
- CCDC105 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs544963596, COSV52964684; called by muse, mutect2, varscan2
- CCDC138 | c.933G>T p.Q311H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1393236343; called by muse, mutect2, varscan2
- CCDC39 | c.2738C>A p.A913D | Missense Mutation (SNP) | VAF 192/535 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99866987; called by muse, mutect2, varscan2
- CCDC73 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100068243; called by muse, mutect2, varscan2
- CCDC83 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs775185124; called by muse, mutect2, varscan2
- CCDC83 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs553174518, COSV54700993, COSV54703567; called by mutect2, varscan2
- CCDC87 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs1272593372; called by muse, mutect2, varscan2
- CCDC88B | c.4277C>T p.P1426L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1279620652; called by muse, mutect2
- CD109 | c.3625G>A p.V1209M | Missense Mutation (SNP) | VAF 202/315 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs762950853, COSV54656893; called by muse, mutect2, varscan2
- CD84 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60869814; called by muse, mutect2, varscan2
- CDCA7L | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758712356; called by muse, mutect2, varscan2
- CDH10 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1234614380; called by muse, mutect2, varscan2
- CDH20 | c.2347C>G p.R783G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53011757; called by muse, mutect2, varscan2
- CDH23 | c.4210-3C>A | Splice Region (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99824126; called by muse, mutect2, varscan2
- CDH23 | c.6086G>T p.R2029L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV56496119, COSV99825264; called by muse, mutect2
- CDH6 | c.1582G>T p.A528S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.761); catalogued as COSV54069558, COSV54072543; called by muse, mutect2
- CEACAM21 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as COSV99494326; called by muse, mutect2, varscan2
- CEACAM5 | c.367C>A p.H123N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV55756189; called by muse, mutect2
- CEACAM8 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs1455345407; called by mutect2, varscan2
- CENPI | c.642C>G p.V214= | Splice Region (SNP) | VAF 9/31 reads (29%) | catalogued as COSV54502226; called by muse, mutect2, varscan2
- CEP112 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV67137528; called by muse, mutect2, varscan2
- CEP170 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1189964569; called by muse, varscan2
- CEP295 | c.536A>T p.E179V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1460517225; called by muse, varscan2
- CEP350 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1232753255; called by muse, mutect2, varscan2
- CFAP70 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1465912201, COSV60287608; called by muse, mutect2, varscan2
- CHD7 | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs748119797; called by muse, mutect2, varscan2
- CHEK2 | c.588A>T p.K196N (on ENST00000382580 / NM_001005735.2; = p.K153N on NM_007194.4) | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV60417247; called by muse, mutect2, varscan2
- CHGA | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1461739142; called by muse, mutect2, varscan2
- CHN1 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs781203325; called by muse, mutect2
- CHRNB4 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55716946; called by muse, mutect2, varscan2
- CIC | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.885); catalogued as rs1039062682; called by muse, mutect2, varscan2
- CLCN1 | c.1404C>T p.F468= | Splice Region (SNP) | VAF 45/464 reads (10%) | catalogued as COSV100578225; called by muse, mutect2
- CLEC17A | c.200-1G>A p.X67_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | catalogued as rs1568449955; called by muse, mutect2, varscan2
- CLHC1 | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs929939304; called by muse, mutect2, varscan2
- CLIP1 | c.86-2A>T p.X29_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as rs760410770, COSV100211832; called by muse, mutect2, varscan2
- CLPTM1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773592797, COSV61611044; called by muse, mutect2, varscan2
- CLSPN | c.3289C>T p.Q1097* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV52053897; called by muse, mutect2, varscan2
- CMTM2 | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV51749415; called by muse, mutect2, varscan2
- CNBD1 | c.344T>A p.V115D | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV72916782; called by muse, mutect2, varscan2
- CNTN1 | c.1922C>A p.T641N | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs1364564341; called by muse, mutect2, varscan2
- CNTN6 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV63172880; called by muse, mutect2, varscan2
- COASY | c.1447G>T p.V483F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs747905818; called by muse, mutect2, varscan2
- COIL | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53595656; called by muse, mutect2, varscan2
- COL11A1 | c.2698C>A p.P900T | Missense Mutation (SNP) | VAF 90/462 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV62190247; called by muse, mutect2, varscan2
- COL14A1 | c.4778G>T p.G1593V | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52847741; called by muse, mutect2, varscan2
- COL1A1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1175987778; called by muse, mutect2, varscan2
- COL3A1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 108/437 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.937); catalogued as COSV58590598; called by muse, mutect2, varscan2
- COL4A1 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866316555; called by muse, mutect2, varscan2
- COL4A3 | c.3886G>A p.A1296T | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1044185049, COSV101170538; called by muse, mutect2, varscan2
- COL4A4 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as rs768664524; called by muse, mutect2, varscan2
- COL5A2 | c.3668C>A p.P1223Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV66407675; called by muse, mutect2, varscan2
- COL6A6 | c.5500G>T p.E1834* | Nonsense Mutation (SNP) | VAF 29/279 reads (10%) | catalogued as COSV100650342; called by muse, mutect2, varscan2
- COPS6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57994444; called by muse, mutect2, varscan2
- CPNE4 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.93); catalogued as COSV70193306; called by muse, mutect2, varscan2
- CRACD | c.1813G>A p.G605S | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); catalogued as rs1195704529, COSV99949003; called by muse, mutect2, varscan2
- CREBBP | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as rs757074419, COSV52128434, COSV99062791; called by muse, mutect2, varscan2
- CREBBP | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.262); catalogued as rs1316551993, COSV52120803, COSV52134047; called by muse, varscan2
- CSMD2 | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as COSV53973568; called by muse, mutect2, varscan2
- CSMD3 | c.8669G>T p.G2890V (on ENST00000297405 / NM_001363185.1; = p.G2721V on NM_052900.3) | Missense Mutation (SNP) | VAF 65/423 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV52107666; called by muse, mutect2, varscan2
- CSMD3 | c.7385G>T p.R2462L (on ENST00000297405 / NM_001363185.1; = p.R2358L on NM_052900.3) | Missense Mutation (SNP) | VAF 169/446 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV52296590; called by muse, mutect2, varscan2
- CST2 | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100491289; called by muse, mutect2, varscan2
- CTNNA2 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV58182888; called by muse, mutect2, varscan2
- CTNNA2 | c.2783G>T p.R928L (on ENST00000402739 / NM_001282597.3; = p.R880L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV58158815; called by muse, mutect2, varscan2
- CWF19L2 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs765980805, COSV56508055, COSV56509746; called by muse, mutect2, varscan2
- DAB1 | c.1052A>T p.Q351L (on ENST00000371231; = p.Q318L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as rs374152781; called by muse, mutect2, varscan2
- DCAF8L1 | c.642C>G p.S214R | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV71595487; called by muse, mutect2, varscan2
- DCAF8L2 | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV101445775; called by muse, mutect2, varscan2
- DCBLD1 | c.1640G>C p.G547A | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99757623; called by muse, mutect2, varscan2
- DCDC1 | c.4606C>T p.P1536S (on ENST00000597505 / NM_001367979.1; = p.P643S on NM_020869.3) | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485987033; called by muse, mutect2, varscan2
- DCDC1 | c.3280T>A p.S1094T (on ENST00000597505 / NM_001367979.1; = p.S201T on NM_020869.3) | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs376619719; called by muse, mutect2, varscan2
- DCHS1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.046); catalogued as rs1486676833; called by muse, mutect2, varscan2
- DCX | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as CM980527, COSV57566972; called by muse, mutect2, varscan2
- DEFB119 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1214066742; called by muse, mutect2, varscan2
- DEPDC5 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037878155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKG | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV99403487; called by muse, mutect2, varscan2
- DHRSX | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58133215; called by muse, mutect2, varscan2
- DHX36 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs746029389; called by muse, mutect2
- DMD | c.2512C>A p.Q838K | Missense Mutation (SNP) | VAF 85/401 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as CM950341; called by muse, mutect2, varscan2
- DNAH1 | c.1073G>C p.R358P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101324567; called by muse, mutect2
- DNAH11 | c.4633C>T p.H1545Y | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as COSV60969618, COSV60985006; called by muse, mutect2, varscan2
- DNAH5 | c.8909C>T p.S2970L | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867672282; called by muse, mutect2
- DNAH8 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV100546860, COSV59469132; called by muse, mutect2, varscan2
- DOCK1 | c.1965G>C p.L655F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54737468; called by muse, mutect2, varscan2
- DOCK4 | c.3622G>C p.D1208H | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV69855799; called by muse, mutect2, varscan2
- DPEP2 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52053809; called by muse, mutect2, varscan2
- DPP10 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.405); catalogued as rs867892663, COSV59661594, COSV59680975; called by muse, mutect2, varscan2
- DPP9 | c.1830C>G p.I610M (on ENST00000598800; = p.I639M on NM_139159.5) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as rs1417590611; called by muse, mutect2, varscan2
- DPYSL3 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV58330644; called by muse, mutect2
- DRC1 | c.2120A>G p.Q707R | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV55507581; called by muse, mutect2, varscan2
- DRD5 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs144132215, COSV58576684, COSV58579946; called by muse, mutect2, varscan2
- DSCAML1 | c.3418G>T p.E1140* (on ENST00000321322; = p.E1080* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV58403335; called by muse, mutect2, varscan2
- DSP | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs794728101; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DUSP28 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs758023880; called by muse, mutect2, varscan2
- DVL3 | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.401); catalogued as rs374772871; called by muse, mutect2, varscan2
- DYRK1B | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100546564; called by muse, mutect2, varscan2
- DYRK4 | c.424C>G p.H142D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99157706; called by muse, mutect2
- DYTN | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV71513305; called by muse, mutect2, varscan2
- EEFSEC | c.316+1G>T p.X106_splice | Splice Site (SNP) | VAF 9/99 reads (9%) | catalogued as rs1472345131; called by muse, mutect2
- ELFN1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.975); catalogued as rs1053391649, COSV70035343; called by muse, mutect2, varscan2
- EMD | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63962074; called by muse, mutect2
- ENAH | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.226); catalogued as COSV52870507; called by muse, mutect2, varscan2
- ENGASE | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100286009; called by muse, mutect2, varscan2
- EPS8 | c.1833G>T p.M611I | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55533520; called by muse, mutect2, varscan2
- ERVV-1 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.651); catalogued as rs1242668765; called by mutect2, varscan2
- ETS2 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs755069743, COSV100711230, COSV62872913; called by muse, mutect2, varscan2
- EXT2 | c.979G>T p.G327C (on ENST00000343631; = p.G360C on NM_000401.3) | Missense Mutation (SNP) | VAF 216/477 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59150261; called by muse, mutect2, varscan2
- EYA4 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.373); catalogued as COSV62054176; called by muse, mutect2, varscan2
- EYA4 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 45/228 reads (20%) | catalogued as COSV100765585; called by muse, mutect2, varscan2
- EYS | c.6696C>A p.N2232K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs946318214; called by muse, mutect2, varscan2
- FAM114A2 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59458139; called by muse, mutect2, varscan2
- FAM133A | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100220562; called by muse, mutect2
- FAM13A | c.2013G>T p.R671S | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs773310806, COSV51996928; called by muse, mutect2, varscan2
- FAM160B2 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs748712675; called by muse, mutect2, varscan2
- FAM184B | c.2353G>T p.G785C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1173654985; called by muse, mutect2, varscan2
- FAM193A | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV100218554; called by muse, mutect2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FANCB | c.2507G>T p.R836I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV60761510; called by muse, mutect2, varscan2
- FASLG | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs763787856; called by muse, mutect2, varscan2
- FAT3 | c.12019G>C p.E4007Q | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV53136268; called by muse, mutect2, varscan2
- FBXL5 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV58011677; called by muse, mutect2, varscan2
- FERD3L | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV51762083; called by muse, varscan2
- FGD4 | c.1202A>T p.K401M | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56790042; called by muse, mutect2, varscan2
- FLG | c.10970G>A p.R3657Q | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as rs201687214; called by muse, mutect2, varscan2
- FLG | c.4294G>A p.G1432R | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs145478188, COSV64235797; called by muse, mutect2, varscan2
- FLG | c.2952C>A p.H984Q | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs778026111; called by muse, mutect2, varscan2
- FLNA | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782193139, COSV61042112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs376472014; ClinVar: uncertain significance; called by mutect2, varscan2
- FMO2 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV52950102; called by muse, mutect2, varscan2
- FOLR2 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1019396188; called by muse, mutect2, varscan2
- FOLR2 | c.461G>T p.W154L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53351724; called by muse, mutect2, varscan2
- FOLR2 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53352836; called by muse, mutect2, varscan2
- FOXA1 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.564); catalogued as COSV51649556; called by muse, mutect2, varscan2
- FOXG1 | c.1346C>A p.S449* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | catalogued as COSV57395888; called by muse, mutect2, varscan2
- FOXP3 | c.1142G>A p.W381* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as rs1557115586, COSV100873248; called by muse, mutect2, varscan2
- FSHR | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV100438371; called by muse, mutect2, varscan2
- FSIP2 | c.916dup p.M306Nfs*7 | Frame Shift Ins (INS) | VAF 18/115 reads (16%) | catalogued as rs752330015; called by mutect2, pindel, varscan2
- FSIP2 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 25/169 reads (15%) | catalogued as COSV58101249; called by muse, mutect2, varscan2
- FSTL5 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV100058063; called by muse, mutect2, varscan2
- FSTL5 | c.1125G>T p.L375F | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV60189133; called by muse, varscan2
- FUT5 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV99398517; called by muse, mutect2, varscan2
- FUT6 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.534); catalogued as rs1168766474; called by muse, mutect2, varscan2
- GABRA3 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV64796141; called by muse, mutect2
- GABRG3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as rs756049787, COSV61513199; called by muse, mutect2, varscan2
- GAL3ST2 | c.825G>T p.W275C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402480950; called by muse, mutect2, varscan2
- GALNT18 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV57148824; called by muse, mutect2, varscan2
- GANAB | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60461425, COSV60462204; called by muse, mutect2, varscan2
- GAREM1 | c.1759C>T p.P587S (on ENST00000269209 / NM_001242409.2; = p.P586S on NM_022751.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV52515773; called by muse, mutect2, varscan2
- GDPD2 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.315); catalogued as COSV100978529; called by muse, mutect2, varscan2
- GFRA3 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs749208735, COSV51228178; called by muse, mutect2, varscan2
- GHDC | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779740542; called by mutect2, varscan2
- GHR | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50108924, COSV50118807; called by muse, mutect2, varscan2
- GIGYF1 | c.2278C>T p.L760F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.451); catalogued as rs1337999426; called by muse, mutect2, varscan2
- GIPC1 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61774530; called by muse, mutect2
- GIPR | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54422800, COSV54425793; called by muse, mutect2, varscan2
- GJA3 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1047204525; called by muse, mutect2, varscan2
- GJA9 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62532758; called by muse, mutect2, varscan2
- GLRA1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554083817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLYATL1 | c.566G>A p.G189E (on ENST00000317391 / NM_001354699.1; = p.G220E on NM_080661.4) | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55607552; called by muse, mutect2, varscan2
- GOLGA1 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as rs146171341; called by muse, mutect2, varscan2
- GP6 | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1249823336; called by muse, mutect2, varscan2
- GPR143 | c.455+1G>T p.X152_splice | Splice Site (SNP) | VAF 55/239 reads (23%) | catalogued as CS010560; called by muse, mutect2, varscan2
- GPR33 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV67889395; called by muse, mutect2, varscan2
- GPSM1 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375107438; called by muse, mutect2, varscan2
- GRIK2 | c.2603C>A p.S868Y | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59740380; called by muse, mutect2, varscan2
- GRM7 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100735523; called by muse, mutect2, varscan2
- GRM8 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100285846, COSV58816215; called by muse, mutect2, varscan2
- GSDME | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61651938; called by muse, mutect2
- GSX2 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58843259; called by muse, mutect2
- HAO2 | c.808G>T p.G270W | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58040104; called by muse, mutect2, varscan2
- HAUS8 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs755192318; called by muse, mutect2, varscan2
- HBA1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs35816645, CM004854; called by mutect2, varscan2
- HDGFL1 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.528); catalogued as rs983317409; called by muse, mutect2, varscan2
- HELQ | c.2744G>C p.G915A | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377687319; called by muse, mutect2, varscan2
- HELZ2 | c.4148G>T p.G1383V (on ENST00000467148 / NM_001037335.2; = p.G814V on NM_033405.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101427625; called by muse, mutect2, varscan2
- HES3 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1219036438; called by muse, mutect2, varscan2
- HEXA | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs911398032, COSV99173714; called by muse, mutect2, varscan2
- HMCN1 | c.1957G>C p.V653L | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV54913016; called by muse, mutect2, varscan2
- HMCN1 | c.16100A>G p.Y5367C | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs538747084; called by muse, mutect2, varscan2
- HOXA11 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1162652181; called by muse, mutect2, varscan2
- HOXA9 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs1402492162; called by muse, mutect2, varscan2
- HOXD12 | c.174C>A p.C58* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs894260752; called by muse, mutect2, varscan2
- HRH2 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV51573366; called by muse, mutect2, varscan2
- HRNR | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV64264230; called by muse, mutect2, varscan2
- HSDL2 | c.439C>G p.H147D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV52715467; called by muse, mutect2, varscan2
- HTR2C | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); catalogued as rs1556486848; called by muse, mutect2, varscan2
- HTRA2 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 51/256 reads (20%) | catalogued as rs771374779, COSV99239857; called by muse, mutect2, varscan2
- IFITM1 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99063791; called by muse, mutect2, varscan2
- IGF2R | c.5066A>G p.D1689G | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807041; called by muse, mutect2, varscan2
- IGHV3-33 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as rs774243077; called by muse, mutect2
- IGKV2D-26 | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768745981; called by muse, mutect2, varscan2
- IGLV8-61 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs755160990; called by muse, mutect2, varscan2
- IL5RA | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV99842620; called by muse, mutect2
- IMPA1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.438); catalogued as rs770116448, COSV56271463; called by muse, mutect2, varscan2
- IMPG2 | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs1365333334; called by muse, mutect2, varscan2
- INHA | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as COSV99217500; called by muse, mutect2, varscan2
- INPP5E | c.18G>C p.E6D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs1461388293; called by muse, mutect2, varscan2
- INPP5J | c.1935G>C p.K645N (on ENST00000331075 / NM_001284285.2; = p.K277N on NM_001002837.2) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs760349672; called by muse, mutect2, varscan2
- INSL5 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV58788208, COSV58788385; called by muse, mutect2, varscan2
- IPO11 | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57573173; called by muse, mutect2, varscan2
- IPO13 | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV64894127; called by muse, mutect2, varscan2
- IQSEC2 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1302692296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQUB | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61236782; called by muse, mutect2
- ISG20 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as rs1302983827; called by muse, mutect2, varscan2
- ISLR2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.587); catalogued as COSV62303066; called by muse, mutect2, varscan2
- ITGA1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99250691; called by muse, mutect2, varscan2
- ITGA6 | c.3307C>G p.R1103G (on ENST00000442250; = p.R1064G on NM_001079818.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1273139724, COSV51230719; called by muse, mutect2, varscan2
- KALRN | c.2360C>A p.A787D | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53766204; called by muse, mutect2
- KATNAL1 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as rs1226508651; called by muse, mutect2, varscan2
- KCNA4 | c.783G>T p.L261F | Missense Mutation (SNP) | VAF 93/293 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99080393; called by muse, mutect2, varscan2
- KCNH1 | c.1088G>T p.R363L (on ENST00000271751 / NM_172362.3; = p.R336L on NM_002238.4) | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55082541; called by muse, mutect2, varscan2
- KCNJ10 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17853258, CM164193; called by muse, mutect2, varscan2
- KCNJ12 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs782090964; called by muse, mutect2, varscan2
- KCNN4 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs763819161; called by muse, mutect2, varscan2
- KCNQ1 | c.1686-1G>T p.X562_splice | Splice Site (SNP) | VAF 43/279 reads (15%) | catalogued as CS003072, CS097244; called by muse, mutect2, varscan2
- KCNS3 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 42/293 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58405601; called by muse, mutect2, varscan2
- KCNT2 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV54071707; called by muse, mutect2, varscan2
- KDR | c.3797C>A p.S1266* | Nonsense Mutation (SNP) | VAF 86/411 reads (21%) | catalogued as COSV55780329; called by muse, mutect2, varscan2
- KDR | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs754554605, COSV55775015; called by mutect2, varscan2
- KHDC3L | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100951181; called by muse, mutect2, varscan2
- KHDRBS2 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV55498840; called by muse, mutect2, varscan2
- KIAA1841 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs371301741, COSV99693538; called by muse, mutect2, varscan2
- KIF2B | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV99275073; called by muse, mutect2, varscan2
- KLHDC1 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833447; called by muse, mutect2, varscan2
- KLK9 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs199562910; called by muse, mutect2
- KMT2A | c.5554G>T p.D1852Y | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63283626; called by muse, mutect2, varscan2
- KMT2D | c.14413G>T p.E4805* | Nonsense Mutation (SNP) | VAF 59/128 reads (46%) | catalogued as COSV104396854, COSV56432065; called by muse, mutect2, varscan2
- KNDC1 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.186); catalogued as rs747407995, COSV100465578, COSV58843536; called by muse, mutect2, varscan2
- KRBA1 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV55441638; called by muse, mutect2, varscan2
- KRT17 | c.1204+1G>T p.X402_splice | Splice Site (SNP) | VAF 53/258 reads (21%) | catalogued as COSV60860249; called by muse, mutect2, varscan2
- KRT33B | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761886439; called by muse, varscan2
- KRTAP10-7 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs782266496; called by muse, mutect2, varscan2
- LAMA2 | c.113-1G>T p.X38_splice | Splice Site (SNP) | VAF 152/309 reads (49%) | catalogued as COSV101370822; called by muse, mutect2, varscan2
- LAMA2 | c.7106G>C p.R2369T | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV70353606; called by muse, varscan2
- LAMB4 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 34/348 reads (10%) | catalogued as COSV52729223; called by muse, mutect2
- LARP7 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1287998981; called by muse, mutect2, varscan2
- LATS2 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101231694; called by muse, mutect2, varscan2
- LATS2 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV66876046; called by muse, mutect2, varscan2
- LCE2A | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.349); catalogued as COSV64226801; called by muse, mutect2, varscan2
- LCE2B | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs999874346, COSV100909310; called by muse, varscan2
- LDLRAD1 | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV62810051; called by muse, mutect2, varscan2
- LECT2 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773806450; called by muse, mutect2, varscan2
- LEPR | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as CS153848; called by muse, mutect2, varscan2
- LHCGR | c.1394G>T p.W465L | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99683100; called by muse, mutect2, varscan2
- LINS1 | c.1148G>T p.R383I | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100130073; called by muse, mutect2, varscan2
- LLGL2 | c.2368C>A p.P790T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51363015; called by muse, mutect2, varscan2
- LMBR1 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV62219570, COSV62221805; called by muse, mutect2
- LRP12 | c.2508G>T p.Q836H | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV52629414; called by muse, mutect2, varscan2
- LRRC4C | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs970993511, COSV99539417; called by muse, mutect2, varscan2
- LRRC61 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99784749; called by muse, mutect2, varscan2
- LRRC66 | c.2341C>G p.P781A | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs751441041, COSV58632530; called by muse, mutect2, varscan2
- LRRC7 | c.1171C>G p.R391G (on ENST00000651989 / NM_001370785.2; = p.R358G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV50498205, COSV50559882; called by muse, mutect2, varscan2
- LUC7L2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs907675494; called by muse, mutect2, varscan2
- LY6L | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as rs368418331; called by muse, mutect2, varscan2
- MAFF | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as rs1203790330; called by muse, mutect2, varscan2
- MAGEB6 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as rs151294955; called by muse, mutect2, varscan2
- MAGEC1 | c.2053G>T p.G685W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as COSV53567727; called by muse, mutect2, varscan2
- MAGEC3 | c.909+1G>T p.X303_splice | Splice Site (SNP) | VAF 54/119 reads (45%) | catalogued as rs759499415; called by muse, mutect2, varscan2
- MAGEC3 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.365); catalogued as COSV53577134; called by muse, mutect2, varscan2
- MALRD1 | c.4456G>T p.G1486C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66006955; called by muse, mutect2
- MAN2A1 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99810665; called by muse, mutect2, varscan2
- MAP11 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 23/218 reads (11%) | catalogued as rs373105135; called by mutect2, varscan2
- MAP7D2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs751019582, COSV101107059, COSV65529369; called by muse, varscan2
- MCHR2 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911576; called by muse, mutect2, varscan2
- MDGA1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51792850; called by muse, mutect2, varscan2
- MDGA2 | c.1687G>A p.E563K (on ENST00000399232 / NM_001113498.2; = p.E265K on NM_182830.4) | Missense Mutation (SNP) | VAF 123/404 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1434293101; called by muse, mutect2, varscan2
- MDM2 | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV50704551; called by muse, mutect2, varscan2
- MEGF10 | c.2840G>T p.R947M | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV57247912, COSV99174735; called by muse, mutect2, varscan2
- MEIS2 | c.992G>A p.R331K (on ENST00000561208 / NM_170675.5; = p.R318K on NM_002399.3) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54933755; called by muse, mutect2, varscan2
- MEP1A | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 20/172 reads (12%) | catalogued as rs1396124275, COSV57920557; called by muse, mutect2, varscan2
- MERTK | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV54932503; called by muse, mutect2, varscan2
- METTL11B | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV71528421; called by muse, mutect2, varscan2
- MGMT | c.122C>T p.T41I (on ENST00000306010; = p.T10I on NM_002412.5) | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as rs1029449695; called by muse, mutect2, varscan2
- MICA | c.763del p.D255Mfs*131 | Frame Shift Del (DEL) | VAF 30/139 reads (22%) | catalogued as COSV101319771; called by mutect2, pindel, varscan2
- MINDY3 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1408153069; called by muse, mutect2, varscan2
- MKRN3 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV58808546; called by muse, mutect2, varscan2
- MMP15 | c.1876G>C p.V626L | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.148); catalogued as rs200769934; called by muse, mutect2, varscan2
- MMP9 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755934245, COSV63434478; called by muse, mutect2, varscan2
- MPDZ | c.5513C>G p.S1838C (on ENST00000319217 / NM_001330637.2; = p.S1809C on NM_003829.5) | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs753981773; called by muse, mutect2, varscan2
- MPDZ | c.5051A>T p.D1684V | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335345618; called by muse, varscan2
- MPDZ | c.1720G>C p.G574R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564000195; called by muse, mutect2, varscan2
- MRC1 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1380265793; called by muse, mutect2, varscan2
- MRC2 | c.3881G>T p.R1294L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.13); catalogued as rs756361138, COSV104409380; called by muse, mutect2, varscan2
- MTF1 | c.1541C>G p.S514* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100888647; called by muse, mutect2
- MTMR4 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.439); catalogued as rs201659333; called by muse, mutect2, varscan2
- MTRR | c.1796G>T p.G599V (on ENST00000264668; = p.G572V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52944100; called by muse, mutect2, varscan2
- MUC12 | c.4449C>G p.F1483L (on ENST00000379442; = p.F1340L on NM_001164462.1) | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.159); catalogued as rs1562785171; called by muse, mutect2, varscan2
- MUC12 | c.5461G>T p.G1821C (on ENST00000379442; = p.G1678C on NM_001164462.1) | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV65193517; called by muse, mutect2, varscan2
- MUC16 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV67481892; called by muse, mutect2, varscan2
- MUC17 | c.6938C>G p.S2313C | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60300148; called by muse, mutect2
- MX1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV55820086, COSV55820160; called by muse, mutect2, varscan2
- MXRA5 | c.6899G>T p.R2300L | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776590689, COSV54232424; called by muse, mutect2, varscan2
- MYCBP2 | c.10546G>C p.E3516Q (on ENST00000357337; = p.E3554Q on NM_015057.5) | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); catalogued as COSV62026486; called by muse, mutect2, varscan2
- MYH11 | c.1923C>A p.S641R | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV55544761; called by muse, mutect2, varscan2
- MYO1A | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55656133; called by mutect2, varscan2
- MYO9B | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745558830; called by muse, mutect2, varscan2
- MYOM2 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1246966051; called by muse, mutect2, varscan2
- MYRF | c.265C>A p.P89T (on ENST00000278836 / NM_001127392.3; = p.P80T on NM_013279.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV53889782; called by muse, mutect2, varscan2
- MYT1L | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101218948; called by muse, mutect2, varscan2
- NARS2 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55255282; called by muse, mutect2, varscan2
- NAV1 | c.2390C>A p.S797* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV55226497; called by muse, mutect2, varscan2
- NBPF10 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs587712953, COSV61666419; called by muse, mutect2, varscan2
- NCOA6 | c.5788G>T p.V1930L | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as rs768171771, COSV62861399; called by muse, mutect2, varscan2
- NDUFA12 | c.274A>T p.S92C | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs750540144; called by muse, mutect2, varscan2
- NDUFS4 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 162/482 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV99692461; called by muse, mutect2, varscan2
- NEK11 | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147575246; called by muse, mutect2, varscan2
- NELL1 | c.1715G>T p.W572L | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54342608; called by muse, mutect2, varscan2
- NELL1 | c.1716G>T p.W572C | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV54338168; called by muse, mutect2, varscan2
- NETO1 | c.1281C>A p.C427* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV55010142; called by muse, varscan2
- NEXMIF | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99281694; called by muse, mutect2, varscan2
- NEXMIF | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs1488723000; called by muse, varscan2
- NGF | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV65688742; called by muse, mutect2, varscan2
- NHS | c.2498G>C p.R833P | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66280668; called by muse, mutect2, varscan2
- NLRP10 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100149958; called by muse, mutect2, varscan2
- NLRP3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV60219978, COSV60230909; called by muse, mutect2, varscan2
- NLRP5 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.049); catalogued as COSV101173785; called by muse, mutect2, varscan2
- NLRP7 | c.1812del p.M605Cfs*7 | Frame Shift Del (DEL) | VAF 53/360 reads (15%) | catalogued as COSV100053140; called by mutect2, pindel, varscan2
- NLRP7 | c.1053G>T p.R351S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100053111; called by muse, mutect2
- NME7 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as COSV100891068; called by muse, mutect2, varscan2
- NNAT | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.97); catalogued as COSV99289937; called by muse, mutect2, varscan2
- NOG | c.628C>A p.R210S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs753114116; called by muse, mutect2, varscan2
- NOP53 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1025115901; called by muse, mutect2, varscan2
- NOS1AP | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs771956293; called by muse, mutect2, varscan2
- NPAP1 | c.2172C>G p.Y724* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100276076; called by muse, mutect2, varscan2
- NPAS4 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV60649153; called by muse, mutect2, varscan2
- NPHP4 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as COSV65393620; called by muse, mutect2, varscan2
- NR1H3 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs779302187, COSV101269721, COSV68008357; called by muse, mutect2, varscan2
- NRP1 | c.1967C>G p.S656C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV55160899; called by muse, mutect2, varscan2
- NRXN2 | c.2352G>T p.E784D | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs775220563; called by muse, varscan2
- NRXN3 | c.530G>T p.R177L (on ENST00000557594 / NM_001272020.2; = p.R809L on NM_004796.6) | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55333269; called by muse, mutect2, varscan2
- NT5DC4 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1023101007; called by muse, mutect2, varscan2
- NTN1 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769551467; called by muse, mutect2, varscan2
- NTNG1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV53979231; called by muse, mutect2
- NTNG1 | c.1036A>T p.I346F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.87); catalogued as COSV99637716; called by muse, mutect2, varscan2
- NUMBL | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.681); catalogued as COSV53287404; called by muse, mutect2, varscan2
- NYAP1 | c.974C>A p.P325Q | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454265685, COSV55719217; called by muse, mutect2, varscan2
- OBSCN | c.21940G>A p.D7314N | Missense Mutation (SNP) | VAF 93/666 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs375823186; called by muse, mutect2, varscan2
- OGFR | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs745914511; called by muse, mutect2, varscan2
- OLFML2B | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV54195645; called by muse, mutect2, varscan2
- OR10AG1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV100400205; called by mutect2, varscan2
- OR10J5 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100604856; called by muse, mutect2, varscan2
- OR10K1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56874053; called by muse, mutect2, varscan2
- OR10Q1 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV57472283; called by muse, mutect2, varscan2
- OR13C4 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 43/371 reads (12%) | catalogued as rs1461889993; called by muse, mutect2, varscan2
- OR1E2 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs199921636; called by muse, mutect2, varscan2
- OR2G6 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs370143527; called by muse, mutect2, varscan2
- OR2M2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV62897905; called by muse, mutect2, varscan2
- OR2M3 | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV101513390, COSV71758967; called by muse, mutect2, varscan2
- OR2M4 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100141368, COSV100141577; called by muse, mutect2, varscan2
- OR2T12 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV58776312; called by muse, varscan2
- OR2T2 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 235/1445 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100737731, COSV100737820; called by muse, mutect2, varscan2
- OR2T4 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 136/497 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV63544725; called by muse, mutect2, varscan2
- OR4C13 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs868965139, COSV73648608; called by muse, mutect2, varscan2
- OR4C46 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771873723; called by muse, mutect2, varscan2
- OR4K13 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1191601087; called by muse, varscan2
- OR4Q3 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59180295; called by muse, mutect2, varscan2
- OR52J3 | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984915, COSV66747581; called by muse, mutect2, varscan2
- OR5H15 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV62947879; called by muse, mutect2, varscan2
- OR8K5 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100537193; called by muse, mutect2, varscan2
- ORC5 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764739551; called by muse, mutect2, varscan2
- OTOP3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs769880508, COSV60914660; called by mutect2, varscan2
- P3R3URF-PIK3R3 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | PolyPhen benign (0); catalogued as rs1221837671; called by muse, mutect2
- PABPC3 | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs767208826, COSV55805802; called by muse, mutect2, varscan2
- PADI1 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1401847176; called by muse, mutect2, varscan2
- PAMR1 | c.1588G>C p.D530H (on ENST00000619888 / NM_001001991.3; = p.D547H on NM_015430.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53516573; called by muse, mutect2, varscan2
- PAPPA2 | c.3316C>G p.L1106V | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV62792673; called by muse, mutect2, varscan2
- PARD3B | c.2710G>C p.E904Q (on ENST00000406610 / NM_001302769.2; = p.E835Q on NM_057177.7) | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100594332; called by muse, mutect2, varscan2
- PCBP1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.432); catalogued as COSV57851265; called by muse, mutect2, varscan2
- PCDH11X | c.3941G>T p.S1314I | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV53512742; called by muse, mutect2
- PCDHA1 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100974305; called by muse, mutect2, varscan2
- PCDHA1 | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); catalogued as rs782273016, COSV65375973, COSV65376787; called by muse, mutect2, varscan2
- PCDHA12 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV56489452; called by muse, mutect2, varscan2
- PCDHA6 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1554131019; called by muse, mutect2, varscan2
- PCDHA7 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs141682483; called by muse, mutect2, varscan2
- PCDHA9 | c.2053G>T p.G685C | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV65323547; called by muse, mutect2, varscan2
- PCDHB1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60630604; called by muse, mutect2, varscan2
- PCDHB13 | c.1240A>G p.R414G | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as rs782469518; called by muse, mutect2, varscan2
- PCDHB13 | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV53399637; called by muse, mutect2, varscan2
- PCDHB5 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as rs1554275938, COSV50652336; called by muse, mutect2, varscan2
- PCDHB5 | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as COSV50675289; called by muse, mutect2, varscan2
- PCDHGA12 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); catalogued as rs776737236; called by muse, mutect2, varscan2
- PCDHGA7 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54002050; called by muse, mutect2, varscan2
- PCDHGB1 | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.453); catalogued as COSV54017049; called by muse, mutect2, varscan2
- PCED1A | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1423928535; called by muse, mutect2, varscan2
- PCNX1 | c.2216G>C p.R739P | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV53094297; called by muse, mutect2, varscan2
- PCNX3 | c.5726C>T p.S1909L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.089); catalogued as rs765903644, COSV63138920; called by muse, mutect2
- PDCL2 | c.499T>A p.Y167N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55261369; called by muse, mutect2
- PDE6C | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 53/213 reads (25%) | catalogued as COSV65116825; called by muse, mutect2, varscan2
- PDIA4 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV53724699; called by muse, mutect2, varscan2
- PDS5A | c.2351C>A p.S784Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100337112; called by muse, mutect2, varscan2
- PDS5B | c.1526T>C p.L509S | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59733386; called by muse, mutect2, varscan2
- PDSS1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 53/317 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs766516366, COSV66058195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEAK1 | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56938718, COSV56943656; called by muse, mutect2
- PEAR1 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99440985; called by muse, mutect2, varscan2
- PEG10 | c.134G>C p.R45P (on ENST00000482108 / NM_001040152.2; = p.R79P on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.515); catalogued as COSV71788243; called by muse, varscan2
- PGK1 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs782317638, COSV64831923; called by muse, mutect2, varscan2
- PGK1 | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1228198574; called by muse, mutect2, varscan2
- PHF20 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.14); catalogued as COSV59186680, COSV59186687; called by muse, mutect2, varscan2
- PHLDB2 | c.2081A>G p.D694G | Missense Mutation (SNP) | VAF 67/345 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs1041719469; called by muse, mutect2, varscan2
- PHYKPL | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57426110; called by muse, mutect2
- PIRT | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.127); catalogued as rs201667664; called by muse, mutect2, varscan2
- PITRM1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs770738350, COSV56526098; called by muse, mutect2, varscan2
- PKP3 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58986825; called by muse, mutect2, varscan2
- PLCH1 | c.3875C>G p.S1292C (on ENST00000340059 / NM_001130960.2; = p.S1284C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.221); catalogued as rs767228255; called by muse, mutect2, varscan2
- PLCH1 | c.2528G>C p.G843A (on ENST00000340059 / NM_001130960.2; = p.G855A on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100396190; called by muse, mutect2
- PLD2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99036609; called by muse, mutect2, varscan2
- PLOD2 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV51465503; called by muse, mutect2, varscan2
- PLXNB1 | c.4811G>T p.G1604V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as COSV56490296, COSV99602525; called by muse, mutect2, varscan2
- PLXND1 | c.2584C>A p.R862S | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60710013; called by muse, mutect2
- POC1A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1315359625; called by muse, mutect2, varscan2
- POLA1 | c.3376G>T p.G1126C | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66884319; called by muse, mutect2, varscan2
- POLQ | c.6643C>G p.Q2215E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51751941; called by muse, mutect2, varscan2
- POLR2D | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.896); catalogued as rs1478827154; called by muse, mutect2, varscan2
- POM121L2 | c.2903C>A p.P968H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV101079351, COSV66275788; called by muse, mutect2, varscan2
- POTEF | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as rs1287364995; called by mutect2, varscan2
- POU2F2 | c.1285del p.L429Sfs*34 (on ENST00000526816 / NM_001207025.3; = p.L413Sfs*34 on NM_002698.5) | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | catalogued as rs746693584, COSV60766181; called by mutect2, pindel, varscan2
- POU2F2 | c.883G>T p.G295C (on ENST00000526816 / NM_001207025.3; = p.G279C on NM_002698.5) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100657582; called by muse, mutect2, varscan2
- PPFIA1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs966958852, COSV54138538; called by muse, mutect2
- PPOX | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV99237486; called by muse, mutect2, varscan2
- PPP1R15B | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs758634501; called by muse, mutect2, varscan2
- PPP1R1C | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs541242622; called by muse, mutect2, varscan2
- PPRC1 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53385779, COSV53385800; called by muse, mutect2, varscan2
- PRDM9 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57012148; called by muse, mutect2, varscan2
- PREX2 | c.4594G>T p.G1532C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55807123; called by muse, mutect2
- PRF1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs746431351, COSV100942647; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKAR2A | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs761839330, COSV99605101; called by mutect2, varscan2
- PRKCSH | c.599-1G>A p.X200_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | catalogued as COSV52951239; called by muse, mutect2, varscan2
- PRODH2 | c.1139G>A p.R380Q (on ENST00000301175; = p.R304Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748985073; called by muse, mutect2, varscan2
- PROS1 | c.1424G>T p.C475F | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766692725, CM083046; called by muse, mutect2, varscan2
- PRR12 | c.2564G>T p.R855L (on ENST00000615927; = p.R1676L on NM_020719.3) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV101330765; called by muse, mutect2, varscan2
- PRR16 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs372467907; called by muse, mutect2, varscan2
- PRR16 | c.234C>A p.D78E (on ENST00000407149 / NM_001300783.2; = p.D55E on NM_016644.2) | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65405688; called by muse, mutect2, varscan2
- PRR16 | c.668G>T p.R223L (on ENST00000407149 / NM_001300783.2; = p.R200L on NM_016644.2) | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV65401845; called by muse, mutect2, varscan2
- PSD2 | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs1447990270; called by muse, mutect2, varscan2
- PSG11 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 35/189 reads (19%) | catalogued as rs769018981, COSV100105290, COSV60457450; called by muse, mutect2, varscan2
- PTCH1 | c.747-1G>T p.X249_splice | Splice Site (SNP) | VAF 52/335 reads (16%) | catalogued as COSV59466164; called by muse, mutect2, varscan2
- PTCHD1 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.345); catalogued as COSV65058688; called by muse, mutect2, varscan2
- PTGER4 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV56722080; called by muse, mutect2, varscan2
- PTGR1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV53028505; called by muse, mutect2, varscan2
- PTPN14 | c.2904C>G p.I968M | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65283613; called by muse, mutect2, varscan2
- PTPRC | c.1663T>C p.Y555H | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs111324714; called by muse, mutect2, varscan2
- PTPRN | c.1393C>A p.R465S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV99834502; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV50247880; called by muse, mutect2, varscan2
- RAB4A | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.813); catalogued as COSV64206945, COSV64207000; called by muse, mutect2, varscan2
- RAMP3 | c.57C>A p.C19* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV54244828; called by muse, mutect2
- RBBP4 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | catalogued as COSV59386823; called by muse, mutect2, varscan2
- RBM42 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs769200196; called by muse, mutect2, varscan2
- RBM43 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs753958041; called by muse, varscan2
- RBM47 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55941735; called by muse, mutect2, varscan2
- RELCH | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as COSV56889327; called by muse, mutect2
- RELN | c.3130G>C p.D1044H | Missense Mutation (SNP) | VAF 76/530 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.598); catalogued as rs760250241, COSV59031950; called by muse, mutect2, varscan2
- RERE | c.1327del p.E443Kfs*43 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | catalogued as COSV61940597; called by mutect2, pindel, varscan2
- REXO5 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99759118; called by muse, varscan2
- RGPD3 | c.3050C>A p.T1017N | Missense Mutation (SNP) | VAF 86/622 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.532); catalogued as COSV58746137; called by muse, mutect2, varscan2
- RGPD4 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780184688; called by muse, mutect2, varscan2
- RGS18 | c.468C>A p.H156Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.56); catalogued as COSV66510427; called by muse, mutect2, varscan2
- RHOBTB1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); catalogued as rs1404174046, COSV61960418; called by muse, mutect2, varscan2
- RHOBTB3 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV66102355; called by mutect2, varscan2
- RIC8B | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1033607647; called by muse, mutect2, varscan2
- RIPPLY2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1453940356; called by muse, mutect2, varscan2
- RLBP1 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51529036; called by muse, mutect2, varscan2
- RNF207 | c.1391T>C p.M464T | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1294110020; called by muse, mutect2, varscan2
- RNF213 | c.4702C>A p.P1568T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV60408388; called by muse, mutect2, varscan2
- RNF213 | c.6112G>T p.A2038S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60399293; called by muse, mutect2, varscan2
- RNF216 | c.692C>G p.S231C (on ENST00000425013 / NM_207116.3; = p.S288C on NM_207111.4) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.599); catalogued as rs367746074; called by muse, mutect2, varscan2
- RNLS | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 25/209 reads (12%) | catalogued as COSV100076507; called by muse, mutect2, varscan2
- RORB | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs892503579; called by muse, mutect2, varscan2
- RP1 | c.4207C>G p.L1403V | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99607227; called by muse, mutect2, varscan2
- RPGRIP1L | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV50905239; called by muse, mutect2, varscan2
- RPRD1B | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100987310; called by muse, mutect2, varscan2
- RSL1D1 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63078431; called by muse, mutect2, varscan2
- RTF1 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV67478784; called by muse, mutect2, varscan2
- RTL1 | c.2111C>A p.A704E | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1196286736; called by muse, varscan2
- RTN2 | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV55592293; called by muse, mutect2, varscan2
- RTTN | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs747963368; called by muse, mutect2, varscan2
- RXFP1 | c.1313A>T p.K438M | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57053322; called by muse, mutect2, varscan2
- RYR1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs770370125, COSV62102805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.4258C>A p.R1420S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV100614637; called by muse, mutect2, varscan2
- RYR1 | c.10781G>A p.R3594H | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV62089472; called by muse, mutect2, varscan2
- RYR2 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs376243998, COSV100770737; called by muse, mutect2, varscan2
- RYR2 | c.4240C>T p.R1414W | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs868750680, COSV100769718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.8977G>A p.G2993R | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); catalogued as rs747988805; called by muse, mutect2, varscan2
- RYR2 | c.14221G>T p.A4741S | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100767825, COSV63684127; called by muse, mutect2, varscan2
- SASH1 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs1457600502, COSV66563282; called by muse, mutect2, varscan2
- SBNO2 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.697); catalogued as rs1243843830, COSV62320047; called by muse, mutect2, varscan2
- SCAMP1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1053225677, COSV57240389; called by muse, mutect2, varscan2
- SCARF1 | c.2152G>T p.G718C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53961533; called by muse, mutect2, varscan2
- SCN2A | c.2635G>T p.G879W | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1413024; called by muse, mutect2, varscan2
- SCN3B | c.-25-5T>C | Splice Region (SNP) | VAF 40/214 reads (19%) | catalogued as rs1332850132; called by muse, mutect2, varscan2
- SCN4A | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as rs970080952; called by muse, mutect2, varscan2
- SCN5A | c.4747C>A p.R1583S (on ENST00000333535 / NM_198056.3; = p.R1582S on NM_000335.5) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs45514691, CM100741, COSV61141982; called by muse, mutect2, varscan2
- SCN5A | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV61117894; called by muse, mutect2
- SCYL2 | c.2786G>T p.G929V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100675359; called by muse, mutect2, varscan2
- SDC3 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100232065; called by muse, mutect2, varscan2
- SDK1 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs750313949, COSV67357896; called by muse, mutect2, varscan2
- SDK1 | c.5350G>T p.A1784S | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67355271; called by muse, mutect2, varscan2
- SEMA3G | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs371677116; called by muse, mutect2, varscan2
- SEMA5A | c.2904G>T p.M968I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV66798824; called by muse, mutect2, varscan2
- SERPINA11 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs557049308; called by muse, mutect2, varscan2
- SETD2 | c.1833G>T p.K611N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs575862721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3A2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs749321087; called by muse, mutect2, varscan2
- SFMBT1 | c.2054C>G p.S685C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs774628083, COSV56258207; called by muse, mutect2, varscan2
- SH3TC2 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 131/352 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV60468576; called by muse, mutect2, varscan2
- SHANK2 | c.4741G>A p.A1581T | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as rs782327395, COSV53590560; called by muse, mutect2, varscan2
- SHROOM4 | c.1571A>G p.N524S | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1281855110; called by muse, mutect2, varscan2
- SIGLEC1 | c.3297G>T p.E1099D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52459015; called by muse, mutect2, varscan2
- SIGLEC5 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.45); catalogued as rs748153203; called by muse, mutect2
- SIGLEC6 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100585364, COSV58432420; called by muse, mutect2, varscan2
- SIGLEC6 | c.390C>A p.Y130* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58435076; called by muse, mutect2, varscan2
- SIGLEC6 | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100585622; called by muse, mutect2, varscan2
- SIM2 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.029); catalogued as rs1269598342; called by muse, mutect2, varscan2
- SIRPA | c.1073C>G p.S358* | Nonsense Mutation (SNP) | VAF 19/155 reads (12%) | catalogued as COSV100605182; called by muse, mutect2, varscan2
- SIRPB2 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766223446; called by muse, mutect2, varscan2
- SIX6 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as rs1411196233, COSV59801836, COSV59802580; called by muse, mutect2, varscan2
- SLC17A8 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60125012, COSV60125481; called by muse, mutect2, varscan2
- SLC22A25 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs919021139, COSV60598526; called by muse, mutect2, varscan2
- SLC25A19 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV57467822; called by mutect2, varscan2
- SLC25A45 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs751867667; called by muse, mutect2, varscan2
- SLC26A7 | c.1529C>A p.P510Q | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52594826; called by muse, mutect2, varscan2
- SLC27A6 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322690; called by muse, varscan2
- SLC28A1 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99722531; called by muse, mutect2, varscan2
- SLC2A11 | c.1162+5G>T | Splice Region (SNP) | VAF 22/85 reads (26%) | catalogued as rs1167843678; called by muse, mutect2, varscan2
- SLC2A2 | c.283A>G p.M95V | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV100049440; called by muse, mutect2, varscan2
- SLC30A10 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63076101; called by muse, mutect2, varscan2
- SLC39A12 | c.1648C>A p.L550M (on ENST00000377369 / NM_001145195.2; = p.L513M on NM_152725.3) | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV66197709; called by muse, mutect2, varscan2
- SLC41A1 | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV65651472; called by muse, mutect2, varscan2
- SLC4A3 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1021250485, COSV56097678; called by muse, varscan2
- SLC52A2 | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57352003; called by muse, mutect2, varscan2
- SLC5A12 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.25); catalogued as COSV54818850, COSV99744913; called by muse, mutect2
- SLC5A4 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV56669102, COSV56673583; called by muse, mutect2, varscan2
- SLC6A9 | c.2098C>T p.R700C (on ENST00000360584 / NM_201649.4; = p.R646C on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.353); catalogued as rs531939948; called by muse, mutect2, varscan2
- SLC8A1 | c.2160T>G p.Y720* | Nonsense Mutation (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100245730; called by muse, mutect2, varscan2
- SLC8A1 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1477645873; called by muse, mutect2, varscan2
- SLC9A6 | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 8/188 reads (4%) | catalogued as COSV100857948; called by muse, mutect2
- SLIT2 | c.2994C>A p.N998K | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs759282159; called by muse, mutect2, varscan2
- SLITRK5 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1177599839; called by muse, mutect2, varscan2
- SMG1 | c.3458G>T p.G1153V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1385759076; called by muse, mutect2, varscan2
- SNAP25 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 21/155 reads (14%) | catalogued as COSV54771375; called by muse, mutect2, varscan2
- SNAP29 | c.237+6C>T | Splice Region (SNP) | VAF 27/108 reads (25%) | catalogued as rs770993363; called by muse, mutect2, varscan2
- SP140 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV100614106; called by muse, mutect2, varscan2
- SPAG16 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); catalogued as rs747474099, COSV100531553; called by muse, mutect2, varscan2
- SPAG6 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs747001348; called by muse, mutect2, varscan2
- SPAG6 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV57617998; called by muse, mutect2, varscan2
- SPATA31A3 | c.2729C>A p.P910H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1409221258; called by mutect2, varscan2
- SPATA31A7 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745605048; called by muse, mutect2, varscan2
- SPATA48 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1034165792; called by muse, mutect2, varscan2
- SPTA1 | c.6083G>T p.R2028I | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63751933; called by muse, mutect2, varscan2
- SPTA1 | c.4000C>T p.H1334Y | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as COSV63761219; called by muse, mutect2, varscan2
- SRGAP3 | c.2409-1G>A p.X803_splice | Splice Site (SNP) | VAF 40/198 reads (20%) | catalogued as rs1259113458; called by muse, mutect2, varscan2
- SRSF4 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV65695943; called by muse, mutect2
- ST13 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.1); catalogued as rs921971081, COSV53423803; called by muse, mutect2, varscan2
- STIM1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199799231, COSV56153297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STRIP1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs756540865; called by muse, mutect2, varscan2
- SUGCT | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100005281; called by muse, varscan2
- SUPT3H | c.244C>T p.Q82* (on ENST00000371460 / NM_181356.3; = p.Q71* on NM_003599.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/300 reads (13%) | catalogued as rs756266861; called by muse, varscan2
- SWI5 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1564371822; called by muse, mutect2, varscan2
- SYK | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV65329500; called by muse, mutect2, varscan2
- SYMPK | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs777672570; called by muse, mutect2, varscan2
- SYNPO | c.2118G>T p.Q706H (on ENST00000394243 / NM_001166208.2; = p.Q462H on NM_007286.6) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs1201991374; called by muse, mutect2, varscan2
- SYT14 | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 261/836 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55061152; called by muse, mutect2, varscan2
- SYT16 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs767714989; called by muse, mutect2, varscan2
- SYT2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs758876808; called by muse, mutect2
- TAC1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV59986959; called by muse, mutect2, varscan2
- TACC1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1374630388, COSV52528934; called by muse, mutect2, varscan2
- TAF1B | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs553152964; called by muse, mutect2, varscan2
- TBL3 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs759511429; called by muse, mutect2, varscan2
- TCEAL6 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.21); catalogued as rs782507106; called by muse, mutect2, varscan2
- TCHH | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | PolyPhen benign (0.042); catalogued as rs377273868; called by muse, mutect2, varscan2
- TCL1A | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as COSV68085891; called by muse, varscan2
- TEDC1 | c.1481G>T p.G494V (on ENST00000392523 / NM_001367178.1; = p.G425V on NM_001134875.1) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782700947; called by muse, mutect2, varscan2
- TERF2IP | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs753345034; called by mutect2, varscan2
- TFF2 | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52295778; called by mutect2, varscan2
- TGFBR2 | c.1681G>T p.G561C | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV99848284; called by muse, mutect2, varscan2
- THSD1 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs753290492; called by muse, mutect2, varscan2
- TICAM1 | c.1261G>C p.V421L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1294358833; called by muse, mutect2
- TIGD6 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as rs1001527020; called by muse, mutect2, varscan2
- TKTL2 | c.143T>A p.V48D | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs774680939; called by muse, mutect2, varscan2
- TM9SF3 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100951816; called by muse, mutect2, varscan2
- TMED9 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs761312863; called by muse, mutect2, varscan2
- TMEM171 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771605311, COSV55131688; called by muse, mutect2, varscan2
- TMEM200A | c.1394G>T p.R465I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99759689; called by muse, mutect2, varscan2
- TMEM229B | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479464338; called by muse, mutect2, varscan2
- TMEM247 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs917476729, COSV71363830; called by muse, mutect2, varscan2
- TMEM273 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65154202; called by muse, mutect2, varscan2
- TMEM61 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100987750; called by muse, mutect2, varscan2
- TMEM71 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs866909827; called by muse, mutect2
- TNRC18 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68171823; called by muse, mutect2, varscan2
- TNXB | c.7328G>A p.R2443H (on ENST00000647633; = p.R2196H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs1433515024; called by mutect2, varscan2
- TP73 | c.705C>A p.S235R | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100601348, COSV60698478; called by muse, mutect2, varscan2
- TPP2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV65752225; called by muse, mutect2, varscan2
- TRAK2 | c.2664G>T p.Q888H | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV60276227; called by muse, mutect2, varscan2
- TRAPPC9 | c.2347G>T p.G783W | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV66910368; called by muse, mutect2, varscan2
- TRIM58 | c.957G>T p.W319C | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.192); catalogued as COSV63571481; called by muse, mutect2
- TRIP11 | c.5908G>C p.G1970R | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV50918485; called by muse, mutect2, varscan2
- TRPC5 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.764); catalogued as COSV53286706; called by muse, mutect2, varscan2
- TRPC7 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61458478, COSV61460402; called by muse, varscan2
- TRPM2 | c.2012G>T p.S671I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV100309475; called by muse, mutect2, varscan2
- TRPM4 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53265499; called by muse, mutect2, varscan2
- TRPS1 | c.3335G>T p.R1112L (on ENST00000220888 / NM_001330599.2; = p.R1125L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773593651, COSV55261368; called by muse, mutect2, varscan2
- TRPV1 | c.1070A>G p.E357G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1447987422; called by muse, mutect2
- TTBK1 | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as rs61737937; called by muse, mutect2, varscan2
- TTC21A | c.1119G>A p.G373= | Splice Region (SNP) | VAF 28/145 reads (19%) | catalogued as rs751820881; called by muse, mutect2, varscan2
- TTC3 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV61287989; called by muse, mutect2, varscan2
- TTC39C | c.468C>G p.I156M (on ENST00000317571 / NM_001135993.2; = p.I95M on NM_153211.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV58217258; called by muse, mutect2, varscan2
- TTN | c.72358C>A p.L24120I (on ENST00000591111; = p.L16696I on NM_003319.4) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs775330925; called by muse, mutect2, varscan2
- TTN | c.33715G>T p.E11239* (on ENST00000591111; = p.E10312* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/354 reads (15%) | catalogued as rs766945794; called by muse, mutect2, varscan2
- TTN | c.6490G>T p.A2164S (on ENST00000591111; = p.A2118S on NM_003319.4) | Missense Mutation (SNP) | VAF 51/380 reads (13%) | PolyPhen probably damaging (0.94); catalogued as CM1510358; called by muse, mutect2, varscan2
- TULP1 | c.381C>A p.D127E | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as rs141034619; called by muse, mutect2, varscan2
- TUT1 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1384075424; called by muse, mutect2, varscan2
- UBR1 | c.2535G>T p.K845N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51926784; called by muse, mutect2, varscan2
- UBR5 | c.6425A>T p.H2142L | Missense Mutation (SNP) | VAF 131/382 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV55285333; called by muse, mutect2, varscan2
- UFL1 | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as rs769347640, COSV65150242; called by muse, mutect2, varscan2
- UGGT2 | c.3325C>T p.Q1109* | Nonsense Mutation (SNP) | VAF 54/242 reads (22%) | catalogued as rs1322948576, COSV65074532; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs775057797; called by muse, mutect2, varscan2
- UHRF2 | c.974-1G>T p.X325_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV52792812; called by muse, mutect2, varscan2
- ULBP2 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 60/514 reads (12%) | catalogued as COSV66265663; called by muse, varscan2
- UNC13C | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV52848049; called by muse, mutect2
- UNC93B1 | c.96+3G>A | Splice Region (SNP) | VAF 6/37 reads (16%) | catalogued as rs1271318369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UPP2 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1473278464; called by muse, varscan2
- USH2A | c.6741del p.A2249Pfs*30 | Frame Shift Del (DEL) | VAF 46/324 reads (14%) | catalogued as rs1335175914; called by mutect2, pindel, varscan2
- VN1R4 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs566861600, COSV60805595; called by muse, mutect2, varscan2
- VPS13A | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs771867568; called by muse, mutect2, varscan2
- VPS13A | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62438485; called by muse, mutect2, varscan2
- VWCE | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs146824227; called by muse, mutect2, varscan2
- VXN | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766323693; called by muse, mutect2, varscan2
- WAS | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV64996593; called by muse, mutect2, varscan2
- WDR17 | c.1608G>A p.M536I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as rs1338269517; called by muse, mutect2, varscan2
- WDR55 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs764298466, COSV100298227; called by muse, mutect2, varscan2
- WDR6 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100556404; called by muse, mutect2, varscan2
- WDR70 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV54265428; called by muse, mutect2, varscan2
- WTAP | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs771401662, COSV100603431; called by muse, mutect2, varscan2
- XDH | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65148197; called by muse, mutect2, varscan2
- XIRP2 | c.4073C>A p.P1358Q (on ENST00000628543; = p.P1533Q on NM_152381.6) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99738460; called by muse, mutect2, varscan2
- XIRP2 | c.9565A>G p.I3189V (on ENST00000628543; = p.I3364V on NM_152381.6) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs377363143; called by muse, mutect2, varscan2
- XPNPEP1 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs142133274; called by muse, mutect2, varscan2
- YEATS2 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV100528101; called by muse, mutect2
- ZAP70 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV53853949; called by muse, mutect2, varscan2
- ZBBX | c.2178C>A p.F726L | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56793942; called by muse, mutect2
- ZCWPW2 | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV67498167; called by muse, varscan2
- ZDBF2 | c.6038C>G p.S2013C | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1306849342, COSV65629162, COSV65630039; called by muse, mutect2
- ZEB1 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs776697635; called by muse, mutect2, varscan2
- ZFHX2 | c.3301C>T p.L1101F | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as COSV70219816; called by muse, mutect2, varscan2
- ZFHX4 | c.9001G>T p.G3001* | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | catalogued as COSV50490189; called by muse, mutect2, varscan2
- ZFP91 | c.1587G>T p.M529I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs745339155; called by mutect2, varscan2
- ZFR2 | c.2397C>A p.C799* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs1379732003, COSV53596041, COSV99507269; called by muse, mutect2, varscan2
- ZIC4 | c.899C>A p.S300* | Nonsense Mutation (SNP) | VAF 24/206 reads (12%) | catalogued as COSV101267823; called by muse, varscan2
- ZIC4 | c.780C>A p.S260R | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67171097; called by muse, varscan2
- ZMYM3 | c.3272G>T p.R1091L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100077762; called by muse, mutect2, varscan2
- ZNF135 | c.33G>T p.P11= | Splice Region (SNP) | VAF 20/126 reads (16%) | catalogued as COSV57880403; called by muse, mutect2, varscan2
2,633 further variants in this file (1,537 protein-altering or splice-affecting, 682 silent, 414 other) are not listed here.
